Somatic mutation profile of tumor specimen ALCH-B2SA-TTR1-A (aliquot ALCH-B2SA-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B2SA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,272 days).
Specimen ALCH-B2SA-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb199df8-9a9f-4edd-b62b-6525421a0f11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SA-NB1-A (Blood Derived Normal), aliquot ALCH-B2SA-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82d3b82c-dd54-41fe-864c-ac59bbe05d17

The open-access MAF lists 574 somatic variants for this specimen: 398 protein-altering or splice-affecting, 104 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 355, Silent 104, Intron 30, Nonsense Mutation 22, RNA 16, 5'UTR 11, 3'UTR 9, Splice Site 8, Frame Shift Del 6, Frame Shift Ins 4, 3'Flank 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 113/477 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757943582; called by muse, mutect2
- ABCB6 | c.2228A>G p.K743R | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1208623912; called by muse, mutect2, varscan2
- ABCC12 | c.2630C>T p.T877I | Missense Mutation (SNP) | VAF 48/390 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754356403; called by muse, mutect2, varscan2
- ABCC12 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs374228610, COSV100252371, COSV60912597; called by muse, mutect2, varscan2
- ACTRT2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs753334145; called by muse, mutect2, varscan2
- ADGRE2 | c.714C>A p.C238* | Nonsense Mutation (SNP) | VAF 32/266 reads (12%) | catalogued as COSV100216332; called by muse, varscan2
- ADGRG4 | c.9136G>T p.A3046S | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV54948628; called by muse, mutect2, varscan2
- ANKRD30B | c.3748G>T p.A1250S | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1276832069; called by muse, mutect2
- ASTN1 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100705161; called by muse, mutect2, varscan2
- B3GALT1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); catalogued as COSV59909611; called by muse, mutect2, varscan2
- BMPR1A | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 91/472 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs1310807915; called by muse, mutect2, varscan2
- CACNA1B | c.3338C>A p.A1113E | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53127420; called by muse, mutect2, varscan2
- CASR | c.2365C>T p.R789C (on ENST00000490131; = p.R866C on NM_000388.4) | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CD121612, COSV99948414; called by muse, mutect2, varscan2
- CATSPER1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56411436; called by muse, mutect2, varscan2
- CATSPERB | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303094175; called by muse, mutect2, varscan2
- CCDC171 | c.3494G>T p.W1165L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV52641029; called by muse, mutect2, varscan2
- CCN3 | c.308C>A p.T103K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs751176923; called by muse, mutect2, varscan2
- CDH10 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52580048; called by muse, mutect2
- CDH18 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99933993; called by muse, mutect2, varscan2
- CENPL | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs759796518; called by muse, mutect2, varscan2
- CNTNAP2 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as rs1402650519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99471067; called by muse, mutect2, varscan2
- COL27A1 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs781235729, COSV100620675; called by muse, mutect2, varscan2
- COLEC11 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.155); catalogued as COSV52595437; called by muse, mutect2
- CPAMD8 | c.3754G>T p.A1252S (on ENST00000651564; = p.A1205S on NM_015692.5) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.33); catalogued as COSV71596602; called by muse, mutect2, varscan2
- CPSF7 | c.517C>T p.R173W (on ENST00000394888 / NM_001136040.4; = p.R216W on NM_024811.4) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs141272956; called by muse, mutect2
- CSMD1 | c.6241C>T p.Q2081* (on ENST00000520002; = p.Q2080* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 13/153 reads (8%) | catalogued as COSV59286954, COSV59289188; called by muse, mutect2
- DCHS1 | c.8672G>T p.R2891L | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs60443131; called by muse, mutect2, varscan2
- DDX50 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs1372347407; called by muse, mutect2, varscan2
- DDX55 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs764648878; called by muse, mutect2, varscan2
- DHRS7C | c.825G>T p.M275I (on ENST00000330255 / NM_001220493.2; = p.M274I on NM_001105571.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57649838; called by muse, mutect2, varscan2
- DNAAF3 | c.991G>T p.G331W (on ENST00000524407 / NM_001256715.2; = p.G378W on NM_178837.4) | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs7508641, COSV100787833, COSV61276050; called by muse, mutect2, varscan2
- DNAH7 | c.4797G>A p.M1599I | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1232179847, COSV56760098; called by muse, mutect2, varscan2
- DSEL | c.2383G>T p.V795L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs374315429; called by muse, mutect2, varscan2
- DSPP | c.2500G>T p.D834Y | Missense Mutation (SNP) | VAF 94/630 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56807689; called by muse, mutect2, varscan2
- DYSF | c.4072G>A p.V1358M | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as rs760627822, COSV50553093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXD3 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs762400259; called by muse, mutect2, varscan2
- EYA2 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs770068078; called by muse, mutect2
- FAM171A1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65316829; called by muse, mutect2, varscan2
- FAM189A2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV57384098; called by muse, mutect2
- FAM91A1 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 26/303 reads (9%) | catalogued as rs1254946393; called by muse, mutect2
- FBN3 | c.6623T>A p.V2208E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV54459196; called by muse, mutect2
- FOXL2 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV57726404, COSV57729898; called by muse, mutect2, varscan2
- FREM3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs779645155; called by mutect2, varscan2
- FSCB | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100469674; called by muse, mutect2
- GABRB3 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1325124119, COSV54650674, COSV54680575; called by muse, mutect2, varscan2
- GABRG1 | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54955997, COSV99778949; called by muse, mutect2, varscan2
- GABRG3 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); catalogued as COSV100406060; called by muse, mutect2, varscan2
- GALNT2 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs574340854; called by muse, mutect2, varscan2
- GATAD2B | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 110/451 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1408392480; called by muse, mutect2, varscan2
- GIMAP1 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56188747; called by muse, mutect2, varscan2
- GPBP1L1 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV51967170; called by muse, mutect2, varscan2
- GPR158 | c.3575C>A p.A1192D | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.084); catalogued as COSV100894125; called by muse, mutect2, varscan2
- GRID1 | c.1873G>T p.V625L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs201449834; called by muse, mutect2, varscan2
- HEPACAM2 | c.91G>T p.G31W (on ENST00000394468 / NM_001039372.4; = p.G19W on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59058427; called by muse, mutect2, varscan2
- HSPA12A | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65020853; called by muse, mutect2, varscan2
- HTR3D | c.1228G>C p.E410Q (on ENST00000382489 / NM_001163646.2; = p.E235Q on NM_182537.3) | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV61915730; called by muse, mutect2, varscan2
- IGDCC4 | c.2582C>A p.P861Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as rs576203297; called by mutect2, varscan2
- IGHV1OR15-9 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1258278371; called by muse, mutect2, varscan2
- IL1RAPL1 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369272343; called by muse, mutect2, varscan2
- ITCH | c.1118G>A p.R373H (on ENST00000262650 / NM_001257137.3; = p.R332H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1473065586, COSV99392904; called by muse, mutect2, varscan2
- ITGA4 | c.2887C>A p.L963I | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59203897; called by muse, mutect2, varscan2
- ITPRID2 | c.504-1G>T p.X168_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | catalogued as rs1283145080; called by muse, mutect2
- JAKMIP1 | c.834G>C p.Q278H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99289756; called by muse, mutect2, varscan2
- JHY | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1212177270; called by muse, mutect2, varscan2
- KALRN | c.5581G>T p.A1861S (on ENST00000360013 / NM_001024660.4; = p.A164S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.994); catalogued as rs55755864; called by muse, mutect2, varscan2
- KCNA3 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1557759771; called by muse, mutect2, varscan2
- KCNH2 | c.1830G>C p.K610N | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM139888; called by muse, mutect2, varscan2
- KCNH7 | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.106); catalogued as COSV59812289; called by muse, mutect2, varscan2
- KEAP1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV50339578; called by muse, varscan2
- KHDRBS2 | c.277del p.E93Kfs*15 | Frame Shift Del (DEL) | VAF 92/325 reads (28%) | catalogued as COSV55429110; called by mutect2, pindel, varscan2
- KLHL20 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV52942577; called by muse, mutect2, varscan2
- KMT2C | c.2357C>A p.T786K | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs1279128165, COSV51471881; called by muse, varscan2
- KRTAP26-1 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.56); catalogued as COSV62128948; called by muse, mutect2, varscan2
- KRTAP4-2 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs374053955, COSV66658662; called by muse, mutect2, varscan2
- LCE1C | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV64219173; called by muse, mutect2
- LPIN2 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 161/420 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs779538504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC4C | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53423667; called by muse, mutect2, varscan2
- LRRTM4 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV69139172, COSV69140181; called by muse, mutect2, varscan2
- MAGT1 | c.152G>C p.R51T (on ENST00000618282 / NM_001367916.1; = p.R83T on NM_032121.5) | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV63783129; called by muse, mutect2, varscan2
- MAPK8IP1 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 26/268 reads (10%) | catalogued as rs868353161; called by muse, mutect2
- MLXIPL | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs868971099; called by muse, mutect2, varscan2
- MROH7 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as rs368337420; called by muse, mutect2, varscan2
- MYL3 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as rs199474707, CM062895, CM1412322; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NLGN1 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV100849959; called by muse, mutect2, varscan2
- OGDHL | c.2189G>T p.W730L | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1036718892, COSV100934479; called by muse, mutect2, varscan2
- ONECUT3 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs1455086691; called by muse, varscan2
- OR10G8 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as COSV70908251; called by muse, mutect2, varscan2
- OR10S1 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73342995; called by muse, mutect2, varscan2
- OR11G2 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV62132294; called by muse, mutect2
- OR11G2 | c.460del p.A154Qfs*21 | Frame Shift Del (DEL) | VAF 19/208 reads (9%) | catalogued as COSV100640021; called by mutect2, pindel, varscan2
- OR11H12 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 34/352 reads (10%) | catalogued as COSV101612483; called by muse, mutect2, varscan2
- OR11L1 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63316066; called by muse, mutect2, varscan2
- OR2T34 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs1348194250, COSV100170265; called by muse, mutect2, varscan2
- OR2W3 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831913; called by muse, mutect2
- OR2W3 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV100831609; called by muse, mutect2, varscan2
- OR4C6 | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV58603612; called by muse, mutect2, varscan2
- OR5H15 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100736609; called by muse, mutect2
- OR6B1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as rs1217664623, COSV68770427; called by muse, mutect2, varscan2
- PAPPA | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100075006; called by muse, mutect2, varscan2
- PDE1C | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs755452839; called by muse, mutect2, varscan2
- PGAP4 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1007368948, COSV66387412; called by muse, mutect2, varscan2
- PIK3C2G | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 72/230 reads (31%) | catalogued as rs775670304; called by muse, mutect2, varscan2
- PLCL1 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70822660; called by muse, mutect2, varscan2
- PLPPR4 | c.1026C>A p.D342E | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV64567132; called by muse, mutect2, varscan2
- POLK | c.2528G>T p.R843M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54031648; called by muse, mutect2, varscan2
- POTEG | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1391923146; called by muse, mutect2, varscan2
- PRAMEF19 | c.1211T>A p.L404Q | Missense Mutation (SNP) | VAF 22/612 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101069241; called by muse, mutect2
- PRR22 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100288572; called by muse, mutect2, varscan2
- PSG7 | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.769); catalogued as rs184944789, COSV68445003; called by muse, mutect2, varscan2
- RAB25 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV63108741; called by muse, mutect2, varscan2
- RGS7 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 54/595 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202033477, COSV58554179; called by muse, mutect2
- RINL | c.1306G>C p.D436H (on ENST00000591812 / NM_001195833.2; = p.D322H on NM_198445.4) | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV61574212; called by muse, mutect2
- SCN2A | c.5152G>T p.G1718* | Nonsense Mutation (SNP) | VAF 58/487 reads (12%) | catalogued as rs1553463525; called by muse, mutect2, varscan2
- SLC16A1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.29); catalogued as rs754077369; called by muse, mutect2, varscan2
- SLC35A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.208); catalogued as COSV54429387; called by muse, mutect2, varscan2
- SLC35D1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 62/601 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs544752539; called by muse, mutect2, varscan2
- SLITRK2 | c.2031C>A p.H677Q | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs200374760, COSV100157471; called by muse, mutect2, varscan2
- SPATA31D1 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV61198959; called by muse, mutect2, varscan2
- SPNS1 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100209149; called by muse, mutect2, varscan2
- ST7 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 54/248 reads (22%) | PolyPhen benign (0.007); catalogued as COSV100127906; called by muse, mutect2, varscan2
- SZT2 | c.5134G>T p.G1712W (on ENST00000634258 / NM_001365999.1; = p.G1655W on NM_015284.4) | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); catalogued as COSV65173075; called by muse, mutect2, varscan2
- TAMALIN | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.046); catalogued as rs1352802067; called by muse, mutect2
- TARS2 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.175); catalogued as COSV60872737; called by muse, mutect2, varscan2
- THSD4 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763120009, COSV55971553; called by muse, mutect2, varscan2
- TMEM132C | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV59419682; called by muse, mutect2, varscan2
- TP53 | c.955A>T p.K319* | Nonsense Mutation (SNP) | VAF 35/230 reads (15%) | catalogued as COSV52675685, COSV52909445; called by muse, mutect2, varscan2
- TRPC4 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58992688; called by muse, mutect2, varscan2
- TRPC6 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs752330361; called by muse, mutect2, varscan2
- TRPM6 | c.3705G>T p.E1235D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV100666715; called by muse, mutect2, varscan2
- UNC80 | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV55895448; called by muse, mutect2, varscan2
- USP42 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1296416712, COSV100084367; called by muse, mutect2, varscan2
- WDR59 | c.1907C>G p.S636C | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as rs753078025; called by muse, mutect2
- WIPF1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); catalogued as rs371993338; called by muse, mutect2, varscan2
- XIRP2 | c.5636A>C p.N1879T (on ENST00000628543; = p.N2054T on NM_152381.6) | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as COSV54727731; called by muse, mutect2, varscan2
- ZNF804A | c.3552C>A p.F1184L | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV56464736; called by muse, mutect2, varscan2
- ZNF804B | c.3446C>G p.T1149R | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60852616; called by muse, mutect2, varscan2
- AC025575.2 | n.180G>T | Splice Region (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- ACAN | c.2794C>A p.P932T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by muse, varscan2
- ADAMTS16 | c.2362G>C p.V788L | Missense Mutation (SNP) | VAF 70/438 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADGRA2 | c.2524C>A p.L842M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRE2 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); called by muse, varscan2
- ADGRV1 | c.15244C>A p.Q5082K | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AKAP6 | c.3445del p.D1149Mfs*8 | Frame Shift Del (DEL) | VAF 53/261 reads (20%) | called by mutect2, pindel, varscan2
- AMOTL1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ANKRD30B | c.446G>T p.S149I | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD34B | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD49 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKRD6 | c.1336A>C p.K446Q | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ANKRD66 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ANO3 | c.1261T>A p.L421I | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF25 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ARHGEF28 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- ASIC3 | c.1088C>G p.S363W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ASL | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 82/288 reads (28%) | called by muse, mutect2, varscan2
- ATM | c.4983C>G p.H1661Q | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BOD1L1 | c.8374G>T p.D2792Y | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- BPIFB6 | c.1148T>A p.L383Q | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BRWD3 | c.4700C>T p.P1567L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CACNA1B | c.2485C>A p.P829T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CACNA1C | c.2980G>T p.V994L | Missense Mutation (SNP) | VAF 122/355 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CACNA1C | c.5028G>T p.E1676D | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CAMSAP1 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CASD1 | c.228C>T p.I76= | Splice Region (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- CASD1 | c.1816-2A>T p.X606_splice | Splice Site (SNP) | VAF 27/203 reads (13%) | called by muse, mutect2, varscan2
- CBLN2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CBWD1 | c.588G>T p.L196F | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC150 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CCDC178 | c.1966G>T p.A656S (on ENST00000383096 / NM_001105528.3; = p.A618S on NM_198995.3) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCR2 | c.292T>A p.W98R | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC14C | c.1408C>A p.L470I (on ENST00000428251; = p.L363I on NM_152627.3) | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH18 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CDH7 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM6 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CECR2 | c.4261C>A p.Q1421K (on ENST00000342247 / NM_001290047.2; = p.Q1237K on NM_001290046.1) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CENPQ | c.579A>C p.E193D | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CEP152 | c.4694G>T p.G1565V (on ENST00000380950 / NM_001194998.2; = p.G1509V on NM_014985.4) | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- CEP290 | c.4247G>T p.R1416L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP295 | c.898T>C p.W300R | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2
- CETN1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CFAP43 | c.3428C>A p.P1143H | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP61 | c.1842C>A p.Y614* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- CHCHD1 | c.328A>T p.R110W | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD9 | c.2774G>C p.R925T | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CNOT2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); called by muse, mutect2
- COBL | c.2595C>A p.S865R | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL19A1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- COL5A2 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COLGALT2 | c.1586T>A p.M529K | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- COMTD1 | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- COMTD1 | c.112T>A p.W38R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COX6A2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CPXM1 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPZ | c.950A>T p.Q317L (on ENST00000360986 / NM_001014447.3; = p.Q306L on NM_003652.3) | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CRISPLD1 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- CUL3 | c.2075G>T p.R692M | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CWH43 | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CX3CR1 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYFIP2 | c.2600T>A p.V867D (on ENST00000616178 / NM_001291722.2; = p.V842D on NM_014376.4) | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CYP1B1 | c.63del p.T22Rfs*19 | Frame Shift Del (DEL) | VAF 30/290 reads (10%) | called by mutect2, varscan2
- CYP26B1 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- CYP26B1 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP39A1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DACH2 | c.605C>A p.P202Q | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- DDX10 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX3X | c.1493C>T p.A498V (on ENST00000399959; = p.A499V on NM_001356.5) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DICER1 | c.5072C>G p.S1691C | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DMD | c.6031C>A p.L2011I | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAI2 | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 146/456 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPT | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 102/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- E4F1 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.057); called by muse, mutect2
- EIF3B | c.1894A>T p.N632Y | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ELAC2 | c.368-1G>T p.X123_splice | Splice Site (SNP) | VAF 36/348 reads (10%) | called by muse, mutect2, varscan2
- EPB41L2 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EPRS1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.08); called by muse, mutect2
- ERICH3 | c.1579C>G p.P527A | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM131C | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM240A | c.236C>A p.P79Q (on ENST00000444264; = p.P73Q on NM_001195442.2) | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FAT3 | c.5284G>C p.E1762Q | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- FEZF2 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 32/204 reads (16%) | called by muse, mutect2, varscan2
- FGF12 | c.634T>C p.S212P (on ENST00000454309 / NM_021032.5; = p.S150P on NM_004113.6) | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- FOXI3 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GABRG1 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- GAPVD1 | c.3978C>G p.F1326L (on ENST00000394104; = p.F1335L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- GCM1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GIGYF1 | c.2916G>T p.Q972H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GIMD1 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- GJA10 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2
- GJC2 | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GK2 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GMNC | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- GNAS | c.1129G>C p.G377R | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GPLD1 | c.1184A>C p.H395P | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GPR149 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM8 | c.2038_2039insT p.G680Vfs*12 | Frame Shift Ins (INS) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- GRXCR1 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HDAC11 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by mutect2, varscan2
- HDAC11 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HDAC9 | c.2378G>T p.C793F | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HEATR1 | c.4058T>G p.V1353G | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- HEATR1 | c.4057G>C p.V1353L | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- HERC2 | c.6760G>C p.V2254L | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HHIPL1 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HTR3A | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IGHV3-66 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 128/401 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.019); called by muse, varscan2
- IGKV1-16 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- IGKV1D-8 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- IGLV5-37 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF22 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL10RB | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- ILDR2 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ILF2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 56/321 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INPP5D | c.535G>C p.E179Q (on ENST00000445964 / NM_001017915.3; = p.E178Q on NM_005541.5) | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- IQCE | c.131-4C>T | Splice Region (SNP) | VAF 89/455 reads (20%) | called by muse, mutect2, varscan2
- ITGA10 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ITIH5 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KANSL1L | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- KBTBD13 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNA6 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNA6 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KCNJ4 | c.1254G>C p.E418D | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL40 | c.1318T>C p.F440L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT26 | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA1 | c.1961T>G p.I654S | Missense Mutation (SNP) | VAF 93/694 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LCE4A | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LDB1 | c.180C>G p.H60Q (on ENST00000425280 / NM_001321612.2; = p.H24Q on NM_003893.5) | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- LEFTY2 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LINC02448 | n.405+1G>T | Splice Site (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- LMBR1 | c.916-1G>T p.X306_splice | Splice Site (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- LNX1 | c.1560G>T p.M520I (on ENST00000263925 / NM_001126328.3; = p.M424I on NM_032622.2) | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.5087A>T p.Q1696L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LRP2 | c.7628T>G p.V2543G | Missense Mutation (SNP) | VAF 64/458 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MACF1 | c.7241G>T p.G2414V | Missense Mutation (SNP) | VAF 76/294 reads (26%) | called by muse, mutect2, varscan2
- MAP2 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K4 | c.3449G>T p.R1150L | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPRE2 | c.75dup p.I26Hfs*37 | Frame Shift Ins (INS) | VAF 30/231 reads (13%) | called by mutect2, pindel, varscan2
- MMRN1 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MROH2B | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTA1 | c.1984A>T p.T662S | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MTRES1 | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- MUC16 | c.26260C>A p.P8754T | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYF5 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.1775A>G p.N592S | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MYOCD | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NAALAD2 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 73/448 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- NCAM1 | c.2497G>A p.E833K (on ENST00000316851 / NM_181351.5; = p.E823K on NM_000615.7) | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NECTIN4 | c.1520dup p.H508Tfs*31 | Frame Shift Ins (INS) | VAF 110/469 reads (23%) | called by mutect2, pindel, varscan2
- NF1 | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NKAIN2 | c.613T>A p.Y205N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- NPIPB11 | c.2613G>A p.M871I | Missense Mutation (SNP) | VAF 103/850 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.284); called by muse, varscan2
- NRG3 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NSUN6 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NTSR1 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NUTM2F | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.344); called by mutect2, varscan2
- OR10G9 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR13F1 | c.591A>T p.L197F | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2A14 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR2M2 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- OR2M4 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR2W3 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2Y1 | c.190T>A p.S64T | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- OR4L1 | c.832A>T p.I278F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5R1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5W2 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 119/379 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR6P1 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI6 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP4 | c.4307A>T p.Q1436L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATZ1 | c.189C>G p.S63R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH19 | c.2988A>T p.E996D (on ENST00000373034 / NM_001184880.2; = p.E948D on NM_020766.3) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PCLO | c.324dup p.G109Wfs*4 | Frame Shift Ins (INS) | VAF 36/173 reads (21%) | called by pindel, varscan2
- PDE11A | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PDLIM1 | c.633del p.K211Nfs*62 | Frame Shift Del (DEL) | VAF 23/189 reads (12%) | called by mutect2, pindel, varscan2
- PDP1 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PEAR1 | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX14 | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGF | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- PGLYRP2 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PGRMC1 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIP5K1C | c.717C>G p.N239K | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PLCB1 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 54/708 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- PLEKHF1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PNLIPRP1 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- POU6F2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCG | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRKRA | c.492G>T p.R164S | Missense Mutation (SNP) | VAF 88/552 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.356); called by muse, mutect2
- PRR23C | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PTBP3 | c.886+1G>T p.X296_splice | Splice Site (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- RAD18 | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD51AP2 | c.3324A>T p.R1108S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- REG1B | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPRD1A | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RXFP3 | c.1211T>A p.L404Q | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RYR2 | c.12369G>T p.E4123D | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR3 | c.2039T>C p.L680P | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCARA3 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SCN10A | c.4730T>A p.L1577Q | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCP2 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 99/350 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SDHA | c.1018A>G p.R340G | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC14L5 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SEC23IP | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEMA3E | c.2275C>T p.L759F | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SH3TC1 | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SHCBP1 | c.1532A>T p.K511M | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SHISA6 | c.1132C>A p.L378M (on ENST00000409168 / NM_001173461.1; = p.L429M on NM_207386.4) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIN3A | c.848A>C p.H283P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SKAP1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC37A2 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC3A2 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.364); called by muse, mutect2
- SMCP | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 97/587 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX25 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SORCS3 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.1708G>T p.A570S | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SP140 | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by mutect2, varscan2
- SPAG16 | c.1049T>A p.L350H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPRR1B | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 46/237 reads (19%) | called by muse, mutect2, varscan2
- SPTA1 | c.1780C>A p.L594I | Missense Mutation (SNP) | VAF 156/551 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SUSD2 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SVEP1 | c.8879C>A p.P2960H | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SYT11 | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAAR8 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAF1L | c.3697G>T p.E1233* | Nonsense Mutation (SNP) | VAF 46/362 reads (13%) | called by muse, mutect2, varscan2
- TBC1D10A | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TENM2 | c.39A>T p.R13S | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TEX45 | c.1385C>G p.P462R | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX47 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TIAM2 | c.2595C>A p.C865* | Nonsense Mutation (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- TMCO1 | c.461G>T p.G154V (on ENST00000612311 / NM_001256164.1; = p.G103V on NM_019026.6) | Missense Mutation (SNP) | VAF 109/486 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TMEM132B | c.1699C>A p.H567N | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TMEM175 | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM215 | c.509del p.S170Ifs*76 | Frame Shift Del (DEL) | VAF 27/124 reads (22%) | called by mutect2, pindel, varscan2
- TMEM225B | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.955); called by muse, mutect2
- TMTC1 | c.2488G>T p.G830C (on ENST00000539277 / NM_001193451.2; = p.G722C on NM_175861.3) | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF10D | c.257-1G>T p.X86_splice | Splice Site (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.4524G>T p.R1508S | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TPO | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV19 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIP6 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.175); called by muse, mutect2
- TSGA10IP | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TTBK1 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.13150G>T p.V4384L (on ENST00000591111; = p.V4338L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | PolyPhen benign (0.243); called by muse, mutect2, varscan2
- UPF2 | c.2575-2A>T p.X859_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- USH2A | c.12044C>A p.T4015N | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, varscan2
- VCAN | c.4067C>A p.P1356H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VGF | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- WSCD2 | c.267C>A p.Y89* | Nonsense Mutation (SNP) | VAF 49/187 reads (26%) | called by muse, mutect2, varscan2
- ZFHX3 | c.5831C>A p.A1944D | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ZFHX4 | c.4360G>T p.A1454S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF326 | c.47A>T p.Y16F | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF350 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF423 | c.574C>A p.H192N (on ENST00000563137 / NM_001379286.1; = p.H184N on NM_015069.4) | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF479 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 129/498 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF530 | c.1397G>T p.S466I | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF7 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 29/292 reads (10%) | called by muse, mutect2, varscan2
- ZNF91 | c.2039A>T p.H680L | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF99 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN9 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZZEF1 | c.5248G>T p.A1750S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.7362G>T p.T2454= | Silent (SNP) | VAF 61/242 reads (25%) | catalogued as rs377081983, COSV101447165; called by muse, mutect2, varscan2
- ADGRF2 | c.141T>C p.S47= | Silent (SNP) | VAF 59/182 reads (32%) | called by muse, mutect2, varscan2
- AGPAT4 | c.237G>T p.P79= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV57243889; called by muse, mutect2
- ANKK1 | c.1068G>A p.L356= | Silent (SNP) | VAF 67/210 reads (32%) | catalogued as rs376825165; called by muse, mutect2, varscan2
- ASMT | c.750G>T p.L250= (on ENST00000381229; = p.L278= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/383 reads (16%) | called by muse, mutect2, varscan2
- ATG9A | c.2179C>A p.R727= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- BCL2 | c.159C>T p.P53= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs764877973; called by muse, varscan2
- BICRA | c.2040G>T p.G680= | Silent (SNP) | VAF 44/202 reads (22%) | catalogued as rs757107695; called by muse, mutect2, varscan2
- BOD1L1 | c.8373G>C p.L2791= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as COSV99238628; called by muse, mutect2
- BRD9 | c.1227C>G p.L409= | Silent (SNP) | VAF 66/468 reads (14%) | catalogued as rs1233558979; called by muse, mutect2, varscan2
- C12orf50 | c.429A>T p.T143= | Silent (SNP) | VAF 56/214 reads (26%) | called by muse, mutect2, varscan2
- CASS4 | c.1695G>T p.V565= | Silent (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- CDCA7 | c.879A>T p.R293= (on ENST00000347703 / NM_145810.3; = p.R372= on NM_031942.5) | Silent (SNP) | VAF 39/181 reads (22%) | catalogued as COSV100143678; called by muse, mutect2, varscan2
- CLEC17A | c.1089T>C p.S363= | Silent (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- CNOT1 | c.4197G>T p.R1399= | Silent (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- CNTN3 | c.810C>T p.S270= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- DAB1 | c.121C>A p.R41= | Silent (SNP) | VAF 97/340 reads (29%) | catalogued as COSV59728131; called by muse, mutect2, varscan2
- DCAF8L2 | c.1131C>G p.A377= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- DDI1 | c.432C>A p.A144= | Silent (SNP) | VAF 57/158 reads (36%) | called by muse, mutect2, varscan2
- DOCK10 | c.1860T>A p.A620= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV99290600; called by muse, mutect2
- ESPN | c.420G>T p.L140= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- EVC2 | c.2751G>A p.K917= | Silent (SNP) | VAF 52/570 reads (9%) | called by muse, mutect2
- FAM171B | c.2004G>T p.P668= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV59000273; called by muse, mutect2, varscan2
- FAT3 | c.7635C>T p.L2545= | Silent (SNP) | VAF 68/306 reads (22%) | catalogued as rs974824041; called by muse, mutect2, varscan2
- FAT4 | c.6024G>T p.R2008= | Silent (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- FATE1 | c.220C>A p.R74= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- FCN1 | c.114G>T p.V38= | Silent (SNP) | VAF 34/227 reads (15%) | called by muse, mutect2, varscan2
- FOXG1 | c.1227G>A p.L409= | Silent (SNP) | VAF 47/436 reads (11%) | catalogued as COSV100486954; called by muse, mutect2, varscan2
- FOXQ1 | c.867G>T p.T289= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- GAL | c.141C>T p.A47= | Silent (SNP) | VAF 56/145 reads (39%) | catalogued as rs367644530; called by muse, mutect2, varscan2
- GSDMB | c.453G>A p.T151= | Silent (SNP) | VAF 31/220 reads (14%) | catalogued as rs761547685, COSV58781364, COSV58782153; called by muse, mutect2, varscan2
- H2BC8 | c.240T>C p.R80= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as rs770940533; called by muse, mutect2, varscan2
- HABP2 | c.636G>A p.Q212= | Silent (SNP) | VAF 71/306 reads (23%) | catalogued as rs967245190; called by muse, mutect2, varscan2
- HAS1 | c.18G>T p.A6= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV55788471; called by muse, mutect2, varscan2
- HHIP | c.1836T>C p.C612= | Silent (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- HK2 | c.1302G>T p.L434= | Silent (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- IGHV2OR16-5 | c.99C>T p.P33= | Silent (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- ILF2 | c.843G>T p.L281= | Silent (SNP) | VAF 55/324 reads (17%) | called by muse, mutect2, varscan2
- IRF2BPL | c.717G>T p.L239= | Silent (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- KEL | c.1209C>A p.A403= | Silent (SNP) | VAF 34/280 reads (12%) | catalogued as COSV62337039; called by muse, mutect2, varscan2
- KRT17 | c.1266C>T p.S422= | Silent (SNP) | VAF 62/259 reads (24%) | called by muse, mutect2, varscan2
- KRTAP10-1 | c.810C>A p.S270= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV59956244; called by muse, mutect2, varscan2
- LAMA1 | c.3345C>A p.T1115= | Silent (SNP) | VAF 47/193 reads (24%) | called by muse, mutect2, varscan2
- LBX1 | c.744C>G p.G248= | Silent (SNP) | VAF 41/141 reads (29%) | called by muse, mutect2, varscan2
- LTB4R | c.888G>T p.A296= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- MAML2 | c.1731C>T p.S577= | Silent (SNP) | VAF 69/601 reads (11%) | catalogued as rs1430881358; called by muse, mutect2, varscan2
- MAPK11 | c.525G>A p.A175= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs201347111; called by muse, mutect2, varscan2
- MC4R | c.867A>T p.I289= | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as COSV55353149; called by muse, mutect2
- MDC1 | c.4812C>A p.S1604= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs1210875326; called by muse, mutect2, varscan2
- MLPH | c.1197G>A p.Q399= | Silent (SNP) | VAF 25/237 reads (11%) | called by muse, mutect2, varscan2
- MYH4 | c.5757C>A p.S1919= | Silent (SNP) | VAF 40/288 reads (14%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1296C>A p.L432= | Silent (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- NDST4 | c.651G>T p.G217= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV52130107; called by muse, mutect2, varscan2
- NLRP3 | c.864C>A p.I288= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV60221686; called by muse, mutect2, varscan2
- NOC4L | c.87C>T p.N29= | Silent (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- OR10S1 | c.522C>A p.T174= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as COSV101602516; called by muse, mutect2, varscan2
- OR1J4 | c.372G>T p.V124= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- OR4C16 | c.792C>A p.P264= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV58941008; called by muse, mutect2, varscan2
- OR4N5 | c.423C>T p.C141= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs372623364, COSV61320196; called by muse, mutect2, varscan2
- OR6P1 | c.387C>A p.P129= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- P2RX5 | c.309G>T p.V103= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as rs759453136; called by mutect2, varscan2
- PCDH11X | c.3540C>A p.A1180= | Silent (SNP) | VAF 131/329 reads (40%) | called by muse, mutect2, varscan2
- PDCD11 | c.792G>T p.T264= | Silent (SNP) | VAF 34/289 reads (12%) | catalogued as rs1412060312; called by muse, mutect2, varscan2
- PHYHIPL | c.936C>T p.T312= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV53246059, COSV53252006; called by muse, mutect2
- PIWIL3 | c.2589G>A p.V863= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- PYGL | c.213G>T p.T71= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- RBM15 | c.2034C>T p.S678= | Silent (SNP) | VAF 19/246 reads (8%) | catalogued as rs1353239176; called by muse, mutect2
- RGS6 | c.747C>A p.L249= | Silent (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- RPGR | c.1704C>T p.F568= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- RYR1 | c.12555G>A p.A4185= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs1442355076, COSV62108558; called by muse, mutect2, varscan2
- SALL1 | c.2397C>G p.P799= | Silent (SNP) | VAF 116/499 reads (23%) | catalogued as COSV99192358; called by muse, mutect2, varscan2
- SCP2D1 | c.408G>T p.V136= | Silent (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- SENP7 | c.909G>A p.K303= | Silent (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- SETBP1 | c.1926C>A p.P642= | Silent (SNP) | VAF 99/567 reads (17%) | called by muse, mutect2, varscan2
- SLC39A4 | c.573G>A p.R191= (on ENST00000301305 / NM_001374839.1; = p.R166= on NM_017767.3) | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs782577342; called by muse, mutect2, varscan2
- SLC4A2 | c.342G>T p.P114= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV100055406; called by muse, mutect2, varscan2
- SMCR8 | c.1614A>T p.P538= | Silent (SNP) | VAF 97/374 reads (26%) | called by muse, mutect2, varscan2
- SORCS1 | c.2808C>T p.T936= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as rs1415656734; called by muse, mutect2, varscan2
- SPATA18 | c.1308C>A p.P436= | Silent (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- SPHKAP | c.417C>G p.L139= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as COSV100763730; called by muse, mutect2, varscan2
- SPTA1 | c.4500C>T p.A1500= | Silent (SNP) | VAF 94/578 reads (16%) | catalogued as COSV63759495; called by muse, mutect2, varscan2
- SPTBN5 | c.5064G>T p.T1688= | Silent (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- SRGAP2 | c.3180C>T p.S1060= (on ENST00000624873 / NM_001170637.4; = p.S1061= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs781947479; called by muse, mutect2
- SULF1 | c.291G>T p.G97= | Silent (SNP) | VAF 86/340 reads (25%) | called by muse, mutect2, varscan2
- SV2C | c.363G>A p.R121= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs531923650; called by muse, mutect2, varscan2
- SVEP1 | c.8880T>A p.P2960= | Silent (SNP) | VAF 59/259 reads (23%) | called by muse, mutect2, varscan2
- TBC1D2 | c.447G>C p.P149= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- TBX2 | c.1011G>T p.P337= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- TCHHL1 | c.1797A>C p.T599= | Silent (SNP) | VAF 85/262 reads (32%) | called by muse, mutect2, varscan2
- TECPR1 | c.1131G>T p.A377= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as COSV65784099; called by muse, mutect2, varscan2
- TMEM229A | c.147C>A p.A49= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- TMEM52B | c.126C>G p.L42= (on ENST00000381923 / NM_001079815.1; = p.L22= on NM_153022.4) | Silent (SNP) | VAF 31/134 reads (23%) | called by muse, mutect2, varscan2
- TPO | c.513G>T p.T171= | Silent (SNP) | VAF 89/362 reads (25%) | called by muse, mutect2, varscan2
- TRPM1 | c.1986G>T p.V662= | Silent (SNP) | VAF 26/196 reads (13%) | called by muse, mutect2, varscan2
- UBE2F | c.432C>T p.N144= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- UBR4 | c.13863G>A p.P4621= | Silent (SNP) | VAF 57/213 reads (27%) | catalogued as rs540655585, COSV100920401, COSV64391014; called by muse, mutect2, varscan2
- UNC80 | c.3190C>A p.R1064= | Silent (SNP) | VAF 67/272 reads (25%) | called by muse, mutect2, varscan2
- VCAM1 | c.237G>T p.T79= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as COSV99658470; called by muse, mutect2, varscan2
- VWF | c.6483C>G p.A2161= | Silent (SNP) | VAF 113/318 reads (36%) | called by muse, mutect2, varscan2
- YY2 | c.669G>A p.G223= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as rs776241984; called by muse, mutect2, varscan2
- ZBTB5 | c.1521C>T p.S507= | Silent (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- ZBTB7B | c.6G>T p.G2= (on ENST00000292176; = p.G36= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV52694877; called by muse, varscan2
- ZFHX4 | c.6330C>G p.T2110= | Silent (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.1131A>T p.R377= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- ABCC13 | n.620A>C | RNA (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- AC021218.1 | n.350G>T | RNA (SNP) | VAF 26/233 reads (11%) | called by muse, mutect2, varscan2
- AC114741.1 | n.200G>T | RNA (SNP) | VAF 50/197 reads (25%) | called by muse, mutect2, varscan2
- ADK | c.66-23912G>T | Intron (SNP) | VAF 32/160 reads (20%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4439G>T | Intron (SNP) | VAF 20/98 reads (20%) | catalogued as rs772487066; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73831108 del T | 3'Flank (DEL) | VAF 61/164 reads (37%) | called by mutect2, pindel, varscan2
- AMPH | c.-9C>A | 5'UTR (SNP) | VAF 25/114 reads (22%) | catalogued as rs1255429217; called by muse, mutect2, varscan2
- BAZ2B | c.5660+62A>C | Intron (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- BMT2 | c.160+4361C>G | Intron (SNP) | VAF 16/224 reads (7%) | catalogued as rs17484277; called by muse, mutect2
- BRCA1 | c.4358-2693C>A | Intron (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- C11orf98 | c.-16G>C | 5'UTR (SNP) | VAF 33/135 reads (24%) | catalogued as rs930886721, COSV104418721; called by muse, mutect2, varscan2
- C1orf105 | c.21+9387C>A | Intron (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- C9orf62 | n.194C>A | RNA (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- CARNS1 | c.-235C>T | 5'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs771295553; called by muse, mutect2, varscan2
- CELF4 | c.1165+22C>A | Intron (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- CHUK | c.-22A>T | 5'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- CLSTN1 | c.2748+17G>A | Intron (SNP) | VAF 19/155 reads (12%) | catalogued as rs200480232; called by muse, mutect2, varscan2
- CPPED1 | c.*11C>A | 3'UTR (SNP) | VAF 48/314 reads (15%) | called by muse, mutect2, varscan2
- CREB3L2 | c.319+5447A>T | Intron (SNP) | VAF 50/158 reads (32%) | called by muse, mutect2, varscan2
- DAP | c.*100G>T | 3'UTR (SNP) | VAF 66/273 reads (24%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2300G>C | 3'UTR (SNP) | VAF 34/205 reads (17%) | called by muse, mutect2, varscan2
- DENND10P1 | n.865T>C | RNA (SNP) | VAF 104/238 reads (44%) | called by muse, varscan2
- DENND10P1 | n.866G>T | RNA (SNP) | VAF 106/238 reads (45%) | called by muse, varscan2
- DNM1L | c.-60G>T | 5'UTR (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- DNM2 | c.162-41C>T | Intron (SNP) | VAF 15/93 reads (16%) | catalogued as rs143155298; called by muse, mutect2, varscan2
- EBF3 | c.1759+1096G>T | Intron (SNP) | VAF 33/402 reads (8%) | called by muse, mutect2
- EFHB | chr3:19936187 C>A | 5'Flank (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- EYA4 | c.1210-10T>C | Intron (SNP) | VAF 38/311 reads (12%) | called by muse, mutect2, varscan2
- HAUS3 | c.*3546G>T | 3'UTR (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- HIPK1 | c.3144+31G>T | Intron (SNP) | VAF 59/187 reads (32%) | catalogued as COSV100479531; called by muse, mutect2, varscan2
- IDUA | c.973-21A>T | Intron (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571436 C>A | 3'Flank (SNP) | VAF 48/194 reads (25%) | called by muse, mutect2, varscan2
- LINC01561 | n.618G>T | RNA (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- LMF1 | c.1530-1349G>T | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- MAP3K19 | c.22+1151G>T | Intron (SNP) | VAF 84/303 reads (28%) | called by muse, mutect2, varscan2
- MGAM | c.4618+5558G>A | Intron (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- MIR544A | n.80A>T | RNA (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30364788 C>A | 3'Flank (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.338C>T | RNA (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- MYBPC1 | c.104-15C>T | Intron (SNP) | VAF 52/331 reads (16%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18337437 G>C | 5'Flank (SNP) | VAF 10/48 reads (21%) | called by mutect2, varscan2
- NR2F2-AS1 | n.984A>T | RNA (SNP) | VAF 38/241 reads (16%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109814G>T | Intron (SNP) | VAF 52/412 reads (13%) | called by muse, mutect2, varscan2
- OR2W5 | n.658G>T | RNA (SNP) | VAF 35/384 reads (9%) | catalogued as rs779047712; called by muse, mutect2
- OR2W5 | n.802C>A | RNA (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
- PCBP2 | c.376-609A>G | Intron (SNP) | VAF 11/79 reads (14%) | catalogued as rs752019023; called by muse, mutect2, varscan2
- PDE6G | c.*47G>C | 3'UTR (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- PITX2 | c.390+221G>T | Intron (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- PSCA | c.*362G>T | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- RNF224 | c.-44del | 5'UTR (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- RYR2 | c.*10C>G | 3'UTR (SNP) | VAF 22/194 reads (11%) | called by muse, varscan2
- SAXO2 | c.53+2788G>T | Intron (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- SLC19A2 | c.1031-41T>A | Intron (SNP) | VAF 21/251 reads (8%) | called by muse, mutect2
- SLC3A1 | c.766-390G>A | Intron (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- SNRPN | c.-370G>T | 5'UTR (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- SOX6 | c.445+458G>C | Intron (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034654 G>T | 3'Flank (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- SSPOP | n.2071C>A | RNA (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- SSPOP | n.6239C>T | RNA (SNP) | VAF 26/121 reads (21%) | catalogued as rs746263180; called by muse, mutect2, varscan2
- SSUH2 | n.493A>T | RNA (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- STAT3 | c.1366-26C>G | Intron (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- TBC1D19 | c.-34G>T | 5'UTR (SNP) | VAF 65/235 reads (28%) | called by muse, mutect2, varscan2
- TSPAN32 | c.354+513C>A | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- UBALD2 | c.-16del | 5'UTR (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- UBBP4 | n.426G>T | RNA (SNP) | VAF 26/112 reads (23%) | catalogued as rs1466959789; called by muse, mutect2, varscan2
- UMPS | c.156+974T>C | Intron (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- VAPB | c.*1665G>T | 3'UTR (SNP) | VAF 150/336 reads (45%) | called by muse, varscan2
- VIM | c.1229+40C>A | Intron (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- VLDLR | c.*51C>A | 3'UTR (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- VPS4A | c.-95G>T | 5'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- XKR4 | c.806+60920C>A | Intron (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- ZNF778 | c.-14G>T | 5'UTR (SNP) | VAF 20/206 reads (10%) | catalogued as rs370876547; called by muse, mutect2
